Somatic mutation profile of tumor specimen TCGA-B6-A0RN-01A (aliquot TCGA-B6-A0RN-01A-12D-A099-09) from TCGA case TCGA-B6-A0RN, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 60.4 years (22,077 days).
Specimen TCGA-B6-A0RN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46e3f1fa-16cc-494b-b22e-ec6ee3ee1b19.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A0RN-10A (Blood Derived Normal), aliquot TCGA-B6-A0RN-10A-01D-A099-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4031e8cf-2a52-4345-9be6-165e0202c200

The open-access MAF lists 35 somatic variants for this specimen: 23 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 11, Frame Shift Del 2, RNA 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 56/127 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BTNL9 | c.1328G>A p.R443H | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as COSV59799829; called by muse, mutect2, varscan2
- CBFB | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 184/291 reads (63%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.988); catalogued as COSV52001905; called by muse, mutect2, varscan2
- CCNB3 | c.4104A>T p.E1368D | Missense Mutation (SNP) | VAF 160/380 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV52080367; called by muse, mutect2, varscan2
- CEP170 | c.4630C>T p.L1544F | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.122); catalogued as COSV60515447; called by muse, mutect2, varscan2
- CFAP94 | c.371C>A p.T124K (on ENST00000320267 / NM_001352064.2; = p.T130K on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 126/356 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV57237158; called by muse, mutect2, varscan2
- FBXW12 | c.296C>T p.T99M | Missense Mutation (SNP) | VAF 53/269 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs148596796, COSV56484212; called by muse, mutect2, varscan2
- GABRG2 | c.288G>A p.M96I | Missense Mutation (SNP) | VAF 125/401 reads (31%) | SIFT tolerated (1); PolyPhen possibly damaging (0.899); catalogued as COSV62722985; called by muse, mutect2, varscan2
- GSPT2 | c.1792A>G p.K598E | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.792); catalogued as COSV61215306; called by muse, mutect2, varscan2
- HFM1 | c.4229T>C p.V1410A | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV54038180; called by muse, mutect2, varscan2
- IL33 | c.427T>G p.Y143D | Missense Mutation (SNP) | VAF 73/160 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as COSV67343742; called by muse, mutect2, varscan2
- JUN | c.245del p.Q82Rfs*22 | Frame Shift Del (DEL) | VAF 18/57 reads (32%) | catalogued as COSV64665016; called by mutect2, pindel, varscan2
- LYPD4 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 61/122 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs782345244, COSV58028527; called by muse, mutect2, varscan2
- NEIL1 | c.1118G>A p.R373Q | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs759056574, COSV51246969; called by muse, mutect2, varscan2
- PANK4 | c.178A>G p.K60E | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT tolerated (0.63); PolyPhen benign (0.012); catalogued as COSV65868233; called by muse, mutect2, varscan2
- PTCH1 | c.3391G>A p.V1131M | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.68); catalogued as rs566619057, COSV59470630; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TBL1XR1 | c.854G>T p.G285V | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV61793069; called by muse, mutect2, varscan2
- THBS1 | c.2476A>G p.M826V | Missense Mutation (SNP) | VAF 92/223 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as COSV52956191; called by muse, mutect2, varscan2
- TMEM145 | c.754C>A p.L252I | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.945); catalogued as COSV56627972; called by muse, mutect2, varscan2
- USP54 | c.4012G>C p.G1338R | Missense Mutation (SNP) | VAF 59/144 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as COSV60448471; called by muse, mutect2, varscan2
- ZNF592 | c.2704G>T p.V902L | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs201965611, COSV55439909; called by muse, mutect2, varscan2
- EVI5 | c.1344del p.K448Nfs*16 | Frame Shift Del (DEL) | VAF 162/477 reads (34%) | called by mutect2, pindel, varscan2
- MYH9 | c.2576_2577delinsTTCTC p.E859delinsVL | In Frame Ins (INS) | VAF 64/107 reads (60%) | called by pindel, varscan2*
- ASPM | c.9969G>A p.L3323= | Silent (SNP) | VAF 52/124 reads (42%) | catalogued as COSV54139605; called by muse, mutect2, varscan2
- MLPH | c.1743C>T p.N581= | Silent (SNP) | VAF 31/81 reads (38%) | catalogued as rs767840362, COSV52818617; called by muse, mutect2, varscan2
- NEK1 | c.3537C>T p.C1179= | Silent (SNP) | VAF 91/221 reads (41%) | catalogued as rs772515579, COSV71457710; called by muse, mutect2, varscan2
- PCDHGC3 | c.1497A>G p.Q499= | Silent (SNP) | VAF 36/98 reads (37%) | catalogued as rs760747309, COSV52770959; called by muse, mutect2, varscan2
- PCOLCE | c.672C>G p.A224= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV53830275; called by muse, mutect2, varscan2
- PNPLA6 | c.624C>T p.C208= (on ENST00000414982 / NM_001166111.2; = p.C160= on NM_006702.5) | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV55385917; called by muse, mutect2, varscan2
- RP1 | c.144C>T p.F48= | Silent (SNP) | VAF 66/175 reads (38%) | catalogued as COSV55110759; called by muse, mutect2, varscan2
- SCN4A | c.5292C>T p.D1764= | Silent (SNP) | VAF 40/90 reads (44%) | catalogued as rs773576176, COSV71126767; ClinVar: benign; called by muse, mutect2, varscan2
- SLC2A9 | c.1371C>T p.V457= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as COSV53329518; called by muse, mutect2, varscan2
- WWTR1 | c.909G>T p.G303= | Silent (SNP) | VAF 29/115 reads (25%) | catalogued as COSV62293378; called by muse, mutect2, varscan2
- XKR6 | c.1638C>T p.A546= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs549267712, COSV58659855; called by muse, mutect2, varscan2
- SSPOP | n.5906C>T | RNA (SNP) | VAF 12/36 reads (33%) | catalogued as rs372726453; called by muse, mutect2, varscan2
